Gene-level copy-number profile of tumor specimen TCGA-CM-4752-01A from TCGA case TCGA-CM-4752, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-CM-4752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ac4e20a0-ada6-476c-8dd3-8d0af50ce370.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-4752-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e73484d6-708e-4d8a-b356-0dce91ccd6d2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 812; copy number 2: 11,079; copy number 3: 25,894; copy number 4: 13,452; copy number 5: 2,552; copy number 6: 1,479; copy number 7: 1,476; copy number 8: 2,038; copy number 9: 1,031.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-4752-01A-01D-1406-01): tumor purity 0.38, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,545 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–26,647,305, 429 genes, copy number 7 (broad region; genes not listed).
- chr7:29,122,340–29,514,667, 2 genes, copy number 7 (within-gene range 5–7): AC004593.2, CHN2.
- chr7:29,514,224–57,837,046, 571 genes, copy number 7 (broad region; genes not listed).
- chr8:78,268,637–145,066,685, 1,061 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr13:18,467,172–111,901,264, 1,322 genes, copy number 8 (broad region; genes not listed).
- chr20:15,892,355–64,313,132, 1,160 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 812. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
